Somatic mutation profile of tumor specimen TARGET-30-PARURB-01A (aliquot TARGET-30-PARURB-01A-01D) from TARGET case TARGET-30-PARURB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.0 years (2,178 days).
Specimen TARGET-30-PARURB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d680698f-b83e-4883-b214-5610d9da6955.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARURB-10A (Blood Derived Normal), aliquot TARGET-30-PARURB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3ba06aa-9bf1-46d8-8584-804212becd67

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, 5'UTR 2, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- ABCB11 | c.2524C>A p.Q842K | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55598783; called by muse, mutect2, varscan2
- BAHCC1 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782577895, COSV57032329; called by muse, mutect2, varscan2
- CCDC39 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369208682; called by muse, mutect2
- EEF1AKNMT | c.280C>T p.R94* (on ENST00000361735 / NM_015935.5; = p.R8* on NM_014955.3) | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as rs778822022, COSV62283238; called by muse, mutect2, varscan2
- EPB41L2 | c.1546C>A p.R516S | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61354929, COSV61358281; called by muse, mutect2, varscan2
- LARP1 | c.668C>A p.T223N (on ENST00000518297 / NM_033551.3; = p.T146N on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV60430593; called by muse, mutect2, varscan2
- LGALS12 | c.744dup p.Q249Afs*18 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs951081172; called by mutect2, pindel, varscan2
- LMO3 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53784739; called by muse, mutect2, varscan2
- LRP4 | c.5540C>G p.T1847R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV66138156; called by muse, mutect2, varscan2
- LRRC37A2 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV100238652; called by mutect2, varscan2
- NLRC5 | c.5438C>T p.A1813V | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52661576; called by muse, mutect2, varscan2
- NLRP14 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs756458906, COSV55071177; called by muse, mutect2, varscan2
- NOM1 | c.2087G>T p.C696F | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51982119; called by muse, mutect2, varscan2
- RNMT | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100054943, COSV51089637; called by muse, mutect2, varscan2
- SMC1B | c.141T>A p.F47L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61582161; called by muse, mutect2, varscan2
- SRPRB | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71749187; called by muse, mutect2, varscan2
- TAGAP | c.987C>A p.S329R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.23); catalogued as COSV57852923; called by muse, mutect2, varscan2
- TCTE1 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV65256260; called by muse, mutect2, varscan2
- TNC | c.4427A>G p.N1476S | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.393); catalogued as rs768830012, COSV60789468; called by muse, mutect2, varscan2
- TTN | c.89825G>C p.R29942P (on ENST00000591111; = p.R22518P on NM_003319.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | PolyPhen probably damaging (0.986); catalogued as COSV59921207, COSV60288706; called by muse, mutect2, varscan2
- AHSP | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2
- MYO18A | c.709del p.R237Afs*59 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, pindel, varscan2
- TSPY2 | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.33); PolyPhen benign (0.127); called by mutect2, varscan2
- TTLL6 | c.2435G>T p.C812F (on ENST00000393382 / NM_001130918.3; = p.C505F on NM_173623.3) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.476); called by muse, mutect2
- YAP1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- ADAMTS12 | c.3399C>A p.R1133= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV61275757; called by muse, mutect2, varscan2
- C6 | c.948C>A p.I316= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV54716704; called by muse, mutect2, varscan2
- ITPR3 | c.1293C>T p.I431= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs373612197; called by muse, mutect2, varscan2
- SLC4A3 | c.2034G>A p.T678= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs752530931; called by muse, mutect2, varscan2
- ZNF205 | c.1080C>T p.G360= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as COSV54622682; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827115 T>C | 3'Flank (SNP) | VAF 41/69 reads (59%) | called by muse, mutect2, varscan2
- KCNC2 | c.*1987T>A | 3'UTR (SNP) | VAF 21/49 reads (43%) | catalogued as COSV54377722; called by muse, mutect2, varscan2
- VPS11 | c.-803A>T | 5'UTR (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- VPS11 | c.-802C>T | 5'UTR (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
